Somatic mutation profile of tumor specimen ALCH-AEPO-TTP1-A (aliquot ALCH-AEPO-TTP1-A-1-0-D-A636-36) from ALCHEMIST case ALCH-AEPO, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 52.0 years (19,000 days).
Specimen ALCH-AEPO-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45e97096-2914-4e67-94ef-de47906931ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEPO-NB1-A (Blood Derived Normal), aliquot ALCH-AEPO-NB1-A-1-0-D-A635-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f63ad895-b357-466d-b650-7268cada95bd

The open-access MAF lists 37 somatic variants for this specimen: 23 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 10, Intron 3, Nonsense Mutation 2, Frame Shift Del 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOL6 | c.970G>T p.V324L | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV101290996; called by muse, mutect2, varscan2
- C3 | c.2701G>A p.V901M | Missense Mutation (SNP) | VAF 94/819 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750656770, COSV55573243; called by muse, mutect2, varscan2
- CHRNB1 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 73/611 reads (12%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.905); catalogued as rs745640319; called by muse, mutect2, varscan2
- COL15A1 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 39/288 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as rs755380230; called by muse, mutect2, varscan2
- EHBP1 | c.3299G>A p.R1100H | Missense Mutation (SNP) | VAF 39/360 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1401104128; called by muse, varscan2
- FAT4 | c.14633C>G p.S4878C | Missense Mutation (SNP) | VAF 79/707 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58681662; called by muse, mutect2, varscan2
- SLCO5A1 | c.739G>C p.E247Q | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.751); catalogued as COSV99479170; called by mutect2, varscan2
- SYT9 | c.1204C>T p.R402* | Nonsense Mutation (SNP) | VAF 32/300 reads (11%) | catalogued as rs543709489, COSV59623964; called by muse, mutect2, varscan2
- ASB5 | c.392C>A p.A131E | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.892); called by muse, mutect2
- ATF7IP | c.2811_2814del p.N937Kfs*3 | Frame Shift Del (DEL) | VAF 30/314 reads (10%) | called by pindel, varscan2
- FGF16 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 44/628 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FSIP2 | c.14569G>A p.A4857T | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MPP2 | c.1192G>T p.D398Y (on ENST00000461854 / NM_001278372.2; = p.D374Y on NM_005374.5) | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- NEB | c.19714T>C p.F6572L | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- NLRP9 | c.2725C>T p.L909F | Missense Mutation (SNP) | VAF 21/237 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.668); called by muse, mutect2
- OR4C6 | c.259A>G p.S87G | Missense Mutation (SNP) | VAF 34/342 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.101); called by muse, mutect2
- PI4KA | c.2004+5G>C | Splice Region (SNP) | VAF 31/185 reads (17%) | called by muse, mutect2, varscan2
- PROKR1 | c.994A>T p.M332L | Missense Mutation (SNP) | VAF 71/584 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- SCN1A | c.5998G>A p.E2000K (on ENST00000303395 / NM_001202435.3; = p.E1989K on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/291 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TEDC1 | c.1096C>T p.Q366* (on ENST00000392523 / NM_001367178.1; = p.Q297* on NM_001134875.1) | Nonsense Mutation (SNP) | VAF 20/81 reads (25%) | called by muse, mutect2, varscan2
- TENM3 | c.4397C>T p.A1466V | Missense Mutation (SNP) | VAF 37/273 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TJP1 | c.4948A>G p.I1650V | Missense Mutation (SNP) | VAF 69/686 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TMTC1 | c.2071G>T p.A691S (on ENST00000539277 / NM_001193451.2; = p.A583S on NM_175861.3) | Missense Mutation (SNP) | VAF 41/500 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2
- AC100868.1 | c.1393A>C p.R465= | Silent (SNP) | VAF 80/500 reads (16%) | called by muse, mutect2, varscan2
- CHD5 | c.3483G>A p.V1161= | Silent (SNP) | VAF 19/181 reads (10%) | called by muse, mutect2
- FBN1 | c.90G>A p.E30= | Silent (SNP) | VAF 80/551 reads (15%) | called by muse, mutect2, varscan2
- GSPT2 | c.1812T>A p.G604= | Silent (SNP) | VAF 41/419 reads (10%) | called by muse, mutect2
- MYOM3 | c.2781C>T p.S927= | Silent (SNP) | VAF 22/171 reads (13%) | catalogued as rs1189508160; called by muse, mutect2, varscan2
- PLEKHH3 | c.804G>A p.V268= | Silent (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2
- SCN8A | c.1068T>C p.F356= | Silent (SNP) | VAF 28/213 reads (13%) | called by muse, mutect2, varscan2
- SUPT20HL1 | c.942G>T p.G314= | Silent (SNP) | VAF 55/473 reads (12%) | called by muse, mutect2, varscan2
- TTC24 | c.150C>T p.G50= | Silent (SNP) | VAF 16/121 reads (13%) | called by muse, mutect2, varscan2
- WNK4 | c.2010C>T p.R670= | Silent (SNP) | VAF 61/579 reads (11%) | catalogued as rs1419800760; called by muse, mutect2, varscan2
- CTBP2 | c.59-2267G>T | Intron (SNP) | VAF 44/308 reads (14%) | called by muse, mutect2, varscan2
- TJP1 | c.27+1419dup | Intron (INS) | VAF 24/240 reads (10%) | catalogued as rs1300964273; called by mutect2, pindel
- TM7SF2 | c.1097-114del | Intron (DEL) | VAF 38/384 reads (10%) | called by mutect2, varscan2
- VAPB | c.*3968C>G | 3'UTR (SNP) | VAF 73/549 reads (13%) | called by muse, mutect2, varscan2
